Somatic mutation profile of tumor specimen TCGA-R6-A6DQ-01B (aliquot TCGA-R6-A6DQ-01B-11D-A31U-09) from TCGA case TCGA-R6-A6DQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 74.2 years (27,098 days).
Specimen TCGA-R6-A6DQ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82f3872d-e5a8-4d62-b31b-04c04c26bf15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A6DQ-10A (Blood Derived Normal), aliquot TCGA-R6-A6DQ-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27034112-7e04-4fb6-ae45-234097c102d8

The open-access MAF lists 79 somatic variants for this specimen: 59 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 18, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.973G>T p.G325* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs863224500, COSV52982163, COSV53644278; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs747282897, COSV100074519; called by muse, mutect2
- ADCY9 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.077); catalogued as COSV53581769; called by muse, mutect2, varscan2
- ARID1A | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as COSV61378125; called by mutect2, varscan2
- ATP2B4 | c.491T>C p.L164S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV58180375; called by muse, mutect2, varscan2
- C1S | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs782291560, COSV100196738; called by muse, mutect2, varscan2
- CCR9 | c.977G>A p.R326Q (on ENST00000357632 / NM_031200.3; = p.R314Q on NM_006641.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.044); catalogued as rs201410158, COSV100591752, COSV62939882; called by muse, mutect2, varscan2
- COL6A3 | c.2803C>T p.R935W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472126541; called by muse, mutect2, varscan2
- CRMP1 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs370759908; called by muse, mutect2, varscan2
- CSNK2A2 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV99345189; called by muse, mutect2, varscan2
- DCHS1 | c.6062G>A p.R2021H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs141121553; called by muse, mutect2, varscan2
- FANCB | c.2262C>G p.F754L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.177); catalogued as COSV60760547; called by muse, mutect2, varscan2
- FAT3 | c.11009G>A p.R3670Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.694); catalogued as rs764239176, COSV99961692; called by muse, mutect2, varscan2
- FNDC1 | c.4237C>T p.R1413* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as rs767053118, COSV51948469; called by muse, mutect2, varscan2
- GSDMD | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775348739; called by muse, varscan2
- HECW1 | c.2792-1G>T p.X931_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV67838727; called by muse, mutect2, varscan2
- HS3ST5 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57139857; called by muse, mutect2, varscan2
- KIAA0753 | c.6del p.P3Qfs*11 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as COSV63817941; called by mutect2, pindel, varscan2
- LRP1B | c.6242G>T p.G2081V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV67247295; called by muse, mutect2
- NRG3 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV64554732; called by muse, mutect2, varscan2
- PCDHA4 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100793157, COSV63538698, COSV63546855; called by muse, mutect2, varscan2
- PCDHGC5 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs747366205; called by muse, mutect2, varscan2
- PDGFRA | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs142492533, COSV57271088; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PRAMEF2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs758430078, COSV53578275; called by muse, mutect2, varscan2
- PROX1 | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs148478012; called by muse, mutect2, varscan2
- PXDNL | c.2667G>T p.Q889H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as rs1399918953; called by muse, mutect2, varscan2
- RSPH14 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs145095630; called by muse, mutect2, varscan2
- SERINC1 | c.939G>A p.W313* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100305060; called by mutect2, varscan2
- SERPINA4 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs540841872, COSV54069263; called by muse, mutect2
- SNTG1 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1461192201; called by muse, mutect2
- STON2 | c.2553G>C p.R851S (on ENST00000649389 / NM_001366849.2; = p.R794S on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50843311; called by muse, mutect2, varscan2
- UNKL | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1341934854; called by muse, mutect2, varscan2
- ZNF587 | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100299531; called by muse, mutect2, varscan2
- ZNF835 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV73379402; called by muse, mutect2
- ANK1 | c.2500T>A p.S834T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- ANKS1B | c.2200A>G p.S734G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C5 | c.3845G>A p.G1282D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CELF4 | c.1427T>G p.L476R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COG5 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CSGALNACT2 | c.1561T>C p.F521L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DAAM2 | c.1351_1360del p.F451Nfs*6 | Frame Shift Del (DEL) | VAF 17/39 reads (44%) | called by mutect2, pindel, varscan2
- ELANE | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERBB2 | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- FBXL12 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FKBP6 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- JPH2 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- KRT79 | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- MTMR6 | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO16 | c.1534A>G p.R512G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- NPC1 | c.1893G>A p.M631I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- PAPPA2 | c.2298A>C p.E766D | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- PRDM4 | c.1126+1G>T p.X376_splice | Splice Site (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- RIMS2 | c.2880-2A>T p.X960_splice (on ENST00000666250 / NM_001348490.2; = p.X768_splice on NM_014677.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 40/71 reads (56%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.2276T>C p.V759A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SLC4A7 | c.1085_1088dup p.Q364Gfs*5 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- SMG7 | c.3113G>A p.R1038K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TUBA8 | c.1063A>G p.I355V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- UGT3A1 | c.1568C>T p.T523I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- ZNF501 | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- ABCC12 | c.3258C>T p.S1086= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs771709822, COSV60913187; called by muse, mutect2, varscan2
- EFNB1 | c.1040G>A p.*347= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- FTMT | c.453C>T p.D151= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV58420725; called by muse, mutect2, varscan2
- FUBP3 | c.1527G>A p.P509= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs781262682; called by muse, mutect2, varscan2
- GRIK4 | c.2520C>T p.S840= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1469767294; called by muse, mutect2, varscan2
- GRIK5 | c.2229C>T p.L743= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs879971267; called by muse, mutect2, varscan2
- GZMA | c.654C>T p.C218= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs374569624; called by muse, mutect2, varscan2
- MAGEC2 | c.882T>G p.P294= | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- OR4N5 | c.78G>T p.L26= | Silent (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1296G>A p.S432= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV65333293; called by muse, mutect2
- PCDHB15 | c.1665C>T p.N555= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs1341124588, COSV50858356; called by muse, mutect2, varscan2
- R3HDM1 | c.2172C>T p.V724= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- RADIL | c.1077G>A p.A359= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs775315249; called by muse, mutect2, varscan2
- SEMG2 | c.1578G>A p.K526= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV65647802; called by muse, mutect2
- SIRT2 | c.999G>A p.E333= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- SLC22A12 | c.333C>T p.A111= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs146095398; called by muse, mutect2, varscan2
- SRXN1 | c.309G>A p.A103= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs371093339, COSV101126514; called by muse, mutect2, varscan2
- TULP1 | c.639A>G p.P213= | Silent (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- DCHS2 | n.731C>T | RNA (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- MFSD4B | c.27+2624G>A | Intron (SNP) | VAF 50/88 reads (57%) | catalogued as rs200995803, COSV64348666; called by muse, mutect2, varscan2
